Somatic mutation profile of tumor specimen MP2PRT-PASKSI-TMP1-A (aliquot MP2PRT-PASKSI-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASKSI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,349 days).
Specimen MP2PRT-PASKSI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c41d7480-0c07-4329-8502-28ffce5caaa4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKSI-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKSI-NM1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/012a7064-fbc2-452e-9c16-b518a6e9ed91

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1321G>A p.V441I | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs1166858113, COSV51848796; called by muse, mutect2
- DAPK2 | c.132C>G p.S44R | Missense Mutation (SNP) | VAF 36/482 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.239); called by muse, mutect2
- PRICKLE2 | c.1874G>A p.R625Q (on ENST00000295902; = p.R569Q on NM_198859.4) | Missense Mutation (SNP) | VAF 76/374 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKK1 | c.1746C>T p.Y582= | Silent (SNP) | VAF 36/644 reads (6%) | catalogued as rs373856752; called by muse, mutect2
